Surgical pathology report (de-identified scan), TCGA case TCGA-E7-A678, project TCGA-BLCA (Bladder Urothelial Carcinoma), tissue source site Asterand, specimen TCGA-E7-A678-01A (Primary Tumor).

TSS Patient ID:

Surgical Date:

Gross Description: In bladder, there are an invasive tumor, ill - margins with 4x4x3.5cm in size, soft and gray surface.

Microscopic Description: Tumor cells arrange to form papillary or nest or groups or cords. Tumor cells have moderate and eosinophilic or clear cytoplasm. Nuclei are enlarged and variability in shape and size, irregular nuclear membranes, nucleoli and abnormal chromatin patterns. Mitoses are present. Tumor invades in fat tissue.

Diagnosis Details: Infiltrating urothelial carcinoma, low-grade, infiltrating fat tissue

Comments:

Formatted Path Reports: BLADDER TISSUE CHECKLIST

Specimen type: Cystectomy

Tumor site: Bladder

Tumor size: 4 x 4 x 3.5 cm

Tumor features: None specified

Histologic type: Transitional cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Perivesical tissue (microscopic)

Lymph nodes: Not specified

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

C&C ICD-O-3
Carcinoma, Urothelial NOS
path 8/20/13
Carcinoma, transitional cell,
papillary 8/30/13
Site: Bladder NOS C67.9
JW 5/16/13

Per TSS email, the pathology report states
that "this case has invasion past the
muscularis propria with a stage of T3a."

Source: NCI Genomic Data Commons file 1fe2acc4-0e3e-4b6f-b277-4ec291d90067 (TCGA-E7-A678.21E3AC3F-5CD6-4E9F-8583-B21642258D07.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).